Somatic mutation profile of tumor specimen 0edcba67-0714-4b04-b433-77834e (aliquot 0edcba67-0714-4b04-b433-77834e_D6_1) from CPTAC case 18BR019, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.0 years (24,819 days).
Specimen 0edcba67-0714-4b04-b433-77834e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e703620f-81ab-401c-b865-fb09bb07ff64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 89b91c31-8d75-42cb-bb72-a97657 (Blood Derived Normal), aliquot 89b91c31-8d75-42cb-bb72-a97657_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06580a50-8236-4590-a78c-144100492545

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 3, Splice Site 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.1165T>C p.F389L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs1384669200; called by muse, mutect2, varscan2
- ATP11B | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221736255; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1222C>G p.R408G (on ENST00000357886 / NM_001365728.1; = p.R394G on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV59425658, COSV59426869; called by muse, mutect2, varscan2
- COL8A1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292621126, COSV53743121; called by muse, mutect2, varscan2
- DNMT3A | c.2597+1G>T p.X866_splice | Splice Site (SNP) | VAF 32/107 reads (30%) | catalogued as COSV53069560; called by muse, mutect2, varscan2
- FAM193B | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753646085, COSV61558317; called by muse, mutect2, varscan2
- MED13L | c.2579A>T p.D860V | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM147775; called by muse, mutect2
- NEFM | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 163/620 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55330230, COSV55331398; called by muse, mutect2, varscan2
- SYT3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370714728; called by muse, varscan2
- ZBED4 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99351784; called by muse, mutect2, varscan2
- ZNF438 | c.1531G>T p.V511F | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs148964717; called by muse, mutect2, varscan2
- ZNF559 | c.1314A>T p.E438D | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.534); catalogued as rs773160422; called by muse, mutect2
- AL669918.1 | c.2051C>A p.T684N | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BOD1L1 | c.4244A>G p.D1415G | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX42 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.261); called by muse, mutect2
- DLG2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- DOCK9 | c.5233G>A p.E1745K (on ENST00000376460 / NM_001366676.2; = p.E1746K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NELFB | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN4Y | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PKD1L1 | c.5549T>A p.L1850Q | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA5A | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLC38A3 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SRRM2 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 13/352 reads (4%) | called by muse, mutect2
- ZSWIM2 | c.1453T>G p.Y485D | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CHST13 | c.429G>T p.A143= | Silent (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- OR11H12 | c.366G>A p.L122= | Silent (SNP) | VAF 82/451 reads (18%) | catalogued as rs769862579; called by mutect2, varscan2
- PHKA2 | c.3174C>T p.I1058= | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as rs750028556, COSV66055421; called by muse, mutect2, varscan2
- SLC27A3 | c.2235C>T p.A745= (on ENST00000271857; = p.A617= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/110 reads (5%) | catalogued as rs1247403032; called by muse, mutect2
- SV2B | c.1890C>T p.L630= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2481C>T p.D827= | Silent (SNP) | VAF 162/731 reads (22%) | catalogued as rs1286201473, COSV65872371; called by muse, mutect2, varscan2
- ZNF280B | c.1008C>T p.N336= | Silent (SNP) | VAF 99/340 reads (29%) | catalogued as rs1264268071; called by muse, mutect2, varscan2
- ABHD5 | c.-79del | 5'UTR (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- AL662899.2 | c.367+296G>T | Intron (SNP) | VAF 46/140 reads (33%) | catalogued as rs1271782723, COSV65507683, COSV65508355; called by muse, mutect2, varscan2
- DGKA | c.399+21G>A | Intron (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102106G>T | Intron (SNP) | VAF 77/283 reads (27%) | called by muse, mutect2, varscan2
